Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-ABK4, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-ABK4-TTP1-A (Primary Tumor).

Material description

- A) Upper lobe, right lung
- B) Upper paratracheal lymph nodes
- C) Pretracheal and retrotracheal lymph nodes
- D) Pretracheal and retrotracheal lymph nodes
- E) Subcarinal lymph nodes
- F) Lymph nodes of pulmonary ligament
- G) Hilar lymph nodes

CDDP-YP-ABK4-01-PR

Macro description

A) Pulmonary lobe of 3.5 x 12 x 7 cm with visceral smooth and shining pleura. When you cut, in the subpleural area, there is roundish whitish neof ormation, soft-elastic compactness, polycyclic margins, bigger axis of 0.5 cm, far 0.3 cm from the pleura and 3 cm from the margin of bronchial resection, The remaining pulmonary parenchyma appears to congested aspect.

We close off 7 peribronchial lymph nodes.

Done intraoperative examination on the neof ormation.

(A1 definitive intraoperative examination; A2 margin of bronchial resection; A3 margin of vascular resection; A4 pleural neof ormation; A5-A6 neof ormation; A7 neof ormation - surrounding parenchyma, A8 extralesional pulmonary parenchyma; A10- A1 1 lymph nodes (A9 one lymph node)

B) 2 blackish fragments of 0.4 cm and 0.2 cm of bigger axis

C) An adipose tissue fragment 0.5 cm of bigger axis

D) Many fragments yellow-blackish of bigger axis between 0.3 cm and 0.8 cm

E) One blackish fragment 0.6 cm of bigger axis

F) One blackish fragment 0.4 cm of bigger axis

G) One blackish fragment 0.6 cm of bigger axis

Micro description

A) Solid adenocarcinoma (), infiltrating, with widespread neoplastic vascular embolization. Visceral pleura free. Margins of bronchial and vascular resection without important histological alterations

Metastases of adenocarcinoma in 2 of 7 peribronchial lymph nodes isolated.

Black lung disease and histiocytosis of sinuses in the remaining lymph nodes.

B-G) Lymph nodes free of neoplasm.

Staging pTNM: pT2, pN1

1 CD-0-3

adenocarcinoma, solid type 8130/3

Site: (R) lung, upper lobe C34.1

1 CD-10

C34.11

Source: NCI Genomic Data Commons file cfe99f2e-d119-47b4-952e-a0ff28781441 (CDDP-ABK4-TTP1.FB15689D-26C5-4FC6-AD33-319D9530D78E.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).